Somatic mutation profile of tumor specimen TCGA-DD-A4NG-01A (aliquot TCGA-DD-A4NG-01A-11D-A27I-10) from TCGA case TCGA-DD-A4NG, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 77.3 years (28,234 days).
Specimen TCGA-DD-A4NG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3e51ca4-ada3-414f-8757-e93a9f5bea59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A4NG-10A (Blood Derived Normal), aliquot TCGA-DD-A4NG-10A-01D-A27I-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc7a2c0d-6dcb-4015-a19e-9a467583006c

The open-access MAF lists 82 somatic variants for this specimen: 59 protein-altering or splice-affecting, 14 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 14, Nonsense Mutation 6, Intron 4, Frame Shift Ins 3, 3'UTR 3, Frame Shift Del 3, In Frame Del 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACKR1 | c.508A>T p.T170S | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV63673598; called by muse, mutect2, varscan2
- AKT2 | c.971A>G p.D324G | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV60908118; called by muse, mutect2, varscan2
- C3 | c.3172G>T p.A1058S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.289); catalogued as COSV55576249; called by muse, mutect2, varscan2
- CACNA2D4 | c.2372G>A p.S791N | Missense Mutation (SNP) | VAF 71/196 reads (36%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as COSV54954447; called by muse, mutect2, varscan2
- CANX | c.1496T>A p.I499N | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as COSV56005335; called by muse, mutect2, varscan2
- CCDC30 | c.1523G>A p.S508N (on ENST00000340612; = p.S465N on NM_001080850.3) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.199); catalogued as COSV59607851; called by muse, mutect2, varscan2
- CD1B | c.29C>A p.A10D | Missense Mutation (SNP) | VAF 59/269 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.521); catalogued as rs1021805831, COSV63804675; called by muse, mutect2, varscan2
- CDNF | c.448A>G p.I150V | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.095); catalogued as COSV65806008; called by muse, mutect2, varscan2
- CDYL | c.1019G>C p.R340T (on ENST00000328908 / NM_001368125.1; = p.R286T on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 158/238 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as COSV59360594; called by muse, mutect2, varscan2
- CENPE | c.4609A>G p.I1537V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54384313; called by muse, mutect2, varscan2
- CEP290 | c.4378A>C p.I1460L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV58353608; called by muse, mutect2, varscan2
- CTNND2 | c.2208T>A p.C736* | Nonsense Mutation (SNP) | VAF 66/209 reads (32%) | catalogued as COSV58905706; called by muse, mutect2, varscan2
- CYP27A1 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.241); catalogued as COSV51469187; called by muse, mutect2, varscan2
- DCLRE1C | c.1355G>T p.C452F (on ENST00000378278 / NM_001350965.2; = p.C337F on NM_022487.4) | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1404800146, COSV57954614; called by muse, mutect2, varscan2
- DDX11 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.163); catalogued as rs1427634316, COSV52507258; called by muse, mutect2, varscan2
- DEGS1 | c.562A>T p.I188F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as COSV60379656; called by muse, mutect2, varscan2
- DKK3 | c.805A>T p.S269C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV58869354; called by muse, mutect2, varscan2
- EHHADH | c.454A>G p.I152V | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.633); catalogued as COSV51631436; called by muse, mutect2, varscan2
- FLT3 | c.536A>G p.Q179R | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as COSV54060629; called by muse, mutect2, varscan2
- FRY | c.8326G>A p.V2776M | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.297); catalogued as COSV66573804; called by muse, mutect2, varscan2
- GADL1 | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 68/207 reads (33%) | catalogued as COSV56981876, COSV56983905; called by muse, mutect2, varscan2
- GOLGB1 | c.2638C>T p.Q880* | Nonsense Mutation (SNP) | VAF 27/89 reads (30%) | catalogued as COSV61467893; called by muse, mutect2, varscan2
- HIPK3 | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57563764; called by muse, mutect2, varscan2
- IGLV4-60 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs747059706; called by muse, mutect2
- KCNMB3 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV62895598; called by muse, mutect2, varscan2
- KRT38 | c.301A>G p.N101D | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as rs765108616, COSV55846686; called by muse, mutect2, varscan2
- LHCGR | c.227T>G p.I76R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.609); catalogued as COSV54295618, COSV54299627; called by muse, mutect2, varscan2
- MAP11 | c.1183A>T p.N395Y | Missense Mutation (SNP) | VAF 77/285 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV57587008; called by muse, mutect2, varscan2
- MBOAT2 | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as COSV60010355; called by muse, mutect2, varscan2
- MEGF8 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 32/105 reads (30%) | catalogued as COSV52092376, COSV52101241; called by muse, mutect2, varscan2
- MRPS35 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV50011766; called by muse, mutect2, varscan2
- MUC5B | c.9182C>A p.S3061Y | Missense Mutation (SNP) | VAF 115/393 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.085); catalogued as COSV71593959; called by muse, mutect2
- NBAS | c.5882C>G p.S1961* | Nonsense Mutation (SNP) | VAF 31/74 reads (42%) | catalogued as COSV55729016; called by muse, mutect2, varscan2
- NFS1 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 71/141 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200454792, COSV65054035; called by muse, mutect2, varscan2
- NLGN1 | c.1910G>T p.R637I | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.038); catalogued as COSV64339592, COSV64340030; called by muse, mutect2, varscan2
- NOL7 | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.131); catalogued as COSV50583167; called by muse, mutect2, varscan2
- NXF3 | c.1334C>T p.T445M | Missense Mutation (SNP) | VAF 246/394 reads (62%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.647); catalogued as rs761308991; called by mutect2, varscan2
- RAD1 | c.88A>G p.I30V | Missense Mutation (SNP) | VAF 63/238 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1230877171, COSV57715479; called by muse, mutect2, varscan2
- RBL1 | c.1428G>A p.M476I | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV60330334; called by muse, mutect2, varscan2
- SNRK | c.868C>G p.L290V | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.133); catalogued as COSV56069476; called by muse, mutect2, varscan2
- SNTB1 | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as COSV67327642; called by muse, mutect2
- SPTBN1 | c.5348T>G p.L1783R | Missense Mutation (SNP) | VAF 73/240 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61690567; called by muse, mutect2, varscan2
- ST3GAL6 | c.47A>C p.Y16S | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV54582986; called by muse, mutect2, varscan2
- THBS1 | c.3445G>A p.G1149R | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52953843; called by muse, mutect2, varscan2
- TLR9 | c.1653C>A p.D551E | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62347496; called by muse, mutect2, varscan2
- TNXB | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 89/531 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs1179436412, COSV64483049; called by muse, mutect2, varscan2
- TTN | c.37038A>C p.E12346D (on ENST00000591111; = p.E4922D on NM_003319.4) | Missense Mutation (SNP) | VAF 36/108 reads (33%) | PolyPhen probably damaging (0.99); catalogued as COSV60181119; called by muse, mutect2, varscan2
- UBE2N | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV58868503; called by muse, mutect2, varscan2
- UNC119B | c.355T>G p.S119A | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV60866466; called by muse, mutect2, varscan2
- VAV3 | c.2437G>T p.D813Y | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58386671, COSV58388872; called by muse, varscan2
- WASL | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV56134599; called by muse, mutect2, varscan2
- ADAM19 | c.1944_1946del p.F649del | In Frame Del (DEL) | VAF 38/138 reads (28%) | called by pindel, varscan2
- ANAPC5 | c.398del p.G133Vfs*7 | Frame Shift Del (DEL) | VAF 18/87 reads (21%) | called by mutect2, pindel, varscan2
- APOB | c.10359dup p.V3454Cfs*8 | Frame Shift Ins (INS) | VAF 48/175 reads (27%) | called by mutect2, pindel, varscan2
- FAM120A | c.708dup p.A237Cfs*11 | Frame Shift Ins (INS) | VAF 28/146 reads (19%) | called by mutect2, pindel, varscan2
- KPNA5 | c.401_402del p.K134Ifs*3 | Frame Shift Del (DEL) | VAF 20/47 reads (43%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.859C>T p.L287F | Missense Mutation (SNP) | VAF 48/63 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- TANC2 | c.572dup p.N191Kfs*13 | Frame Shift Ins (INS) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- WEE2 | c.24del p.E9Nfs*2 | Frame Shift Del (DEL) | VAF 45/106 reads (42%) | called by mutect2, pindel, varscan2
- ANGPTL1 | c.864T>C p.H288= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as rs1358532602, COSV52367167; called by muse, mutect2, varscan2
- ANO8 | c.510C>T p.R170= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV50186654; called by muse, mutect2, varscan2
- CACNA1E | c.6489G>A p.P2163= (on ENST00000367573 / NM_001205293.3; = p.P2120= on NM_000721.4) | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as rs377180948, COSV62388209; called by muse, mutect2, varscan2
- DNHD1 | c.5289T>C p.Y1763= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as COSV54439369; called by muse, mutect2, varscan2
- EPS8L1 | c.2103A>T p.S701= (on ENST00000201647 / NM_133180.3; = p.S574= on NM_017729.3) | Silent (SNP) | VAF 60/196 reads (31%) | catalogued as COSV52383967; called by muse, mutect2, varscan2
- JHY | c.351A>G p.Q117= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV56220548; called by muse, mutect2, varscan2
- OR5K3 | c.81G>C p.L27= | Silent (SNP) | VAF 53/200 reads (27%) | catalogued as rs771561906, COSV67350360; called by muse, mutect2, varscan2
- OTOP1 | c.1086G>T p.G362= | Silent (SNP) | VAF 51/166 reads (31%) | catalogued as rs1405393364, COSV56394781; called by muse, mutect2, varscan2
- RASSF8 | c.123C>A p.T41= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV51454308; called by muse, mutect2, varscan2
- TGFB2 | c.774A>G p.T258= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs1271642210, COSV100860034, COSV65110098; called by muse, varscan2
- TMIGD1 | c.252C>T p.S84= | Silent (SNP) | VAF 44/160 reads (28%) | catalogued as COSV61028874; called by muse, mutect2, varscan2
- TMPRSS13 | c.216C>T p.G72= | Silent (SNP) | VAF 16/45 reads (36%) | called by muse, varscan2
- TPCN2 | c.2100G>A p.K700= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV53727710; called by muse, mutect2, varscan2
- UBQLN3 | c.1653G>T p.G551= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV61164771; called by muse, mutect2
- CIAO3 | c.896+9G>A | Intron (SNP) | VAF 29/112 reads (26%) | called by muse, mutect2, varscan2
- EP400 | c.7394+11A>G | Intron (SNP) | VAF 35/103 reads (34%) | catalogued as rs753806770; called by muse, mutect2, varscan2
- FOXE1 | c.*1528G>T | 3'UTR (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100909886; called by muse, mutect2, varscan2
- FXYD6P3 | n.106C>T | RNA (SNP) | VAF 31/42 reads (74%) | called by muse, mutect2, varscan2
- PCBP1 | c.*98dup | 3'UTR (INS) | VAF 17/66 reads (26%) | called by mutect2, pindel, varscan2
- PCDH7 | c.3174+608C>G | Intron (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- RNU6-1191P | chr16:81109199 C>T | 5'Flank (SNP) | VAF 38/134 reads (28%) | catalogued as rs529627344; called by muse, mutect2, varscan2
- TRIM61 | c.526-3555A>G | Intron (SNP) | VAF 15/42 reads (36%) | catalogued as COSV100255986; called by muse, mutect2, varscan2
- ZNF474 | c.*60C>A | 3'UTR (SNP) | VAF 20/55 reads (36%) | catalogued as COSV99682088; called by muse, mutect2, varscan2
